CCDI case PBCDDC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4adb0cff-e999-4ddc-b910-79b0d52242d5

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.2 years (2,615 days).

Biospecimens (3 samples)
- Sample 0DPAO8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPAOE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DPHA6: Tissue type: Tumor; Specimen type: Solid Tissue.
